Somatic mutation profile of tumor specimen ALCH-B2CR-TTP1-A (aliquot ALCH-B2CR-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2CR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.4 years (26,813 days).
Specimen ALCH-B2CR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec992e4d-1149-497f-a01d-4e535f47af30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2CR-NB1-A (Blood Derived Normal), aliquot ALCH-B2CR-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3988940-9996-40f1-94db-19894ff0fea6

The open-access MAF lists 434 somatic variants for this specimen: 285 protein-altering or splice-affecting, 85 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 85, Intron 28, Nonsense Mutation 17, RNA 14, 3'UTR 10, Splice Site 8, 5'UTR 7, Frame Shift Ins 3, 5'Flank 3, Frame Shift Del 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3185A>T p.H1062L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99285963; called by muse, mutect2, varscan2
- ADGB | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as COSV58861572; called by muse, mutect2, varscan2
- ADGRE2 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV59696375; called by mutect2, varscan2
- AHCY | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV54153242; called by muse, mutect2, varscan2
- AP3B1 | c.877A>G p.M293V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs538390986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID4A | c.1266A>T p.K422N | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV62162161; called by muse, mutect2, varscan2
- BCO1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs759269101, COSV50733359; called by muse, mutect2, varscan2
- BMPER | c.1976G>A p.C659Y | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203157762, COSV51825122; called by muse, mutect2, varscan2
- BRPF3 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1442029620; called by muse, varscan2
- C1S | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1555163103, COSV61071827; called by muse, mutect2
- C1orf68 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs868766653; called by muse, mutect2
- C21orf58 | c.310-2A>G p.X104_splice | Splice Site (SNP) | VAF 22/108 reads (20%) | catalogued as rs898430901; called by muse, mutect2, varscan2
- CA5A | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs553928413; called by muse, mutect2, varscan2
- CASP8AP2 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV52747762; called by muse, mutect2, varscan2
- CHD8 | c.4306G>T p.D1436Y (on ENST00000646647 / NM_001170629.2; = p.D1157Y on NM_020920.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63219632; called by muse, mutect2, varscan2
- CORO7 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs764057890; called by muse, mutect2, varscan2
- CSNK1A1L | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.027); catalogued as COSV101131104; called by muse, mutect2, varscan2
- DHTKD1 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1434020455; called by muse, mutect2, varscan2
- DMD | c.5540T>C p.I1847T | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs371728045; called by muse, mutect2, varscan2
- DNAH3 | c.10934G>T p.R3645L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54516732, COSV54559962; called by muse, mutect2, varscan2
- DPY19L3 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs1280289251; called by muse, mutect2, varscan2
- DSG3 | c.1716G>T p.Q572H | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV57127567; called by muse, mutect2, varscan2
- EDAR | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374079078, COSV99304500; called by muse, mutect2
- EEF1A2 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV53204973; called by mutect2, varscan2
- EML6 | c.5420G>A p.R1807H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62872743; called by muse, mutect2, varscan2
- EPB41L3 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs142277051; called by muse, mutect2, varscan2
- FBXW5 | c.1624C>A p.R542S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.439); catalogued as COSV56403924; called by muse, mutect2, varscan2
- FRAS1 | c.8654G>T p.G2885V | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773648567; called by muse, mutect2, varscan2
- GATA6 | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 40/221 reads (18%) | catalogued as COSV52524853; called by muse, mutect2, varscan2
- GLB1 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM094649, COSV100257417; called by muse, mutect2, varscan2
- GPR149 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV67669909; called by muse, mutect2, varscan2
- HCN1 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV57511899; called by muse, mutect2, varscan2
- HCRTR1 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV65485746, COSV65486480; called by muse, mutect2
- HLTF | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59498536; called by muse, mutect2, varscan2
- HOMEZ | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1210897268; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs749096992; called by muse, mutect2, varscan2
- KCND2 | c.1879G>T p.V627F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58589429; called by muse, mutect2, varscan2
- KIF18A | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs139953450; called by muse, mutect2, varscan2
- KLRF2 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as rs1211492206; called by muse, mutect2
- LAMA3 | c.3448G>T p.G1150W | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs745555297; called by mutect2, varscan2
- LPAR4 | c.186T>A p.F62L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs781268173; called by muse, mutect2, varscan2
- LRRC74A | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs761609399; called by muse, mutect2, varscan2
- MAB21L1 | c.876C>G p.D292E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as rs764311301; called by muse, mutect2, varscan2
- MAGEA6 | c.250T>A p.Y84N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61449402; called by muse, varscan2
- MBTPS1 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100597766; called by muse, mutect2, varscan2
- MC3R | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV54763244; called by muse, varscan2
- MOSPD3 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99774980; called by muse, mutect2, varscan2
- MYO3B | c.3358C>T p.H1120Y | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs1277113296; called by muse, mutect2, varscan2
- NAV1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs1302373342; called by muse, mutect2, varscan2
- NLRP2 | c.3023G>A p.C1008Y | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs769085492, COSV99672589; called by muse, mutect2, varscan2
- OR10G8 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368438499; called by muse, mutect2, varscan2
- OR10S1 | c.503C>A p.T168K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs777181185, COSV73343037; called by muse, mutect2, varscan2
- OR14C36 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as COSV58601868; called by muse, mutect2, varscan2
- OR4K15 | c.923C>T p.P308L (on ENST00000305051; = p.P284L on NM_001005486.1) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs866957972, COSV100521102; called by muse, mutect2, varscan2
- OR5D18 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs903944395, COSV61738094; called by muse, mutect2, varscan2
- OR8G5 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV100422188; called by mutect2, varscan2
- PLGRKT | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.342); catalogued as rs1300765751; called by muse, mutect2, varscan2
- RIMS2 | c.3063G>T p.R1021S (on ENST00000666250 / NM_001348490.2; = p.R829S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as COSV51676038; called by muse, mutect2, varscan2
- ROBO3 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1244896145, COSV67300147; called by muse, mutect2, varscan2
- RPS12 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV57766931, COSV57767609; called by muse, mutect2, varscan2
- RYR3 | c.10906A>G p.S3636G (on ENST00000389232; = p.S3637G on NM_001036.6) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs542762625; called by muse, mutect2, varscan2
- SHBG | c.742T>C p.W248R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99352191; called by muse, mutect2, varscan2
- SI | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV52270976; called by muse, mutect2, varscan2
- SLC25A13 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753105901; called by muse, mutect2, varscan2
- SLC35D2 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53565072; called by muse, mutect2, varscan2
- SPACA1 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99389647; called by muse, mutect2
- SV2A | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1326246994, COSV64964392; called by muse, mutect2, varscan2
- TAF1L | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54267068; called by muse, mutect2, varscan2
- TAS2R20 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs745989110; called by muse, mutect2, varscan2
- TCEA2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV58658533; called by muse, mutect2, varscan2
- TCFL5 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs760646699; called by muse, varscan2
- TMEM130 | c.446G>T p.S149I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV59561507; called by muse, mutect2, varscan2
- TNXB | c.8086G>T p.D2696Y (on ENST00000647633; = p.D2449Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV64485876; called by muse, varscan2
- TPTE2 | c.367G>A p.V123I (on ENST00000400230 / NM_199254.2; = p.V86I on NM_130785.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as rs1269235518, COSV99690121; called by muse, mutect2, varscan2
- TRHR | c.815T>A p.V272E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61234928; called by muse, mutect2, varscan2
- TRIM15 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs747110315; called by muse, mutect2, varscan2
- TRIM77 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs990423546; called by muse, mutect2, varscan2
- TTBK1 | c.2902G>T p.G968W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV99444103; called by muse, mutect2, varscan2
- USP31 | c.2654G>A p.G885E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.47); catalogued as COSV99565895; called by mutect2, varscan2
- VIM | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56405167; called by muse, mutect2
- WNT8B | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs745934916; called by muse, mutect2, varscan2
- ZFYVE26 | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as rs1214930730; called by muse, mutect2, varscan2
- ZNF248 | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV61997402; called by muse, mutect2, varscan2
- ZNF438 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1419230225; called by muse, mutect2, varscan2
- ADAMTS17 | c.1516A>T p.T506S | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS20 | c.4697T>A p.V1566E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ADARB2 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADCY1 | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2
- ADGB | c.1803G>T p.L601F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRL3 | c.1201G>C p.E401Q (on ENST00000506720 / NM_001322402.2; = p.E333Q on NM_015236.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGPS | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AHNAK2 | c.10540G>T p.G3514W | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ALPK2 | c.2753C>A p.T918N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ANK2 | c.10450G>T p.E3484* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- ANKRD7 | c.702G>T p.M234I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.168); called by muse, mutect2
- ARFGEF2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, varscan2
- ARFGEF3 | c.4210A>G p.K1404E | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ARMCX2 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2
- ARPC3 | c.7-1G>T p.X3_splice | Splice Site (SNP) | VAF 49/217 reads (23%) | called by muse, mutect2, varscan2
- ASB10 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN1 | c.354G>T p.L118F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BICD1 | c.2755G>T p.A919S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, varscan2
- BRPF3 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C1QL2 | c.553G>C p.G185R | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QL2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C7orf77 | n.147G>T | Splice Region (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- CA8 | c.576+1G>T p.X192_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | called by muse, varscan2
- CACNA1B | c.6128C>A p.P2043H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- CACNA1G | c.3537G>T p.Q1179H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CADM1 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- CCDC178 | c.2441T>C p.L814P (on ENST00000383096 / NM_001105528.3; = p.L776P on NM_198995.3) | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCN2 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCT8L2 | c.96C>G p.H32Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CD101 | c.363T>G p.C121W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD1C | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDNF | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP135 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- CHD7 | c.7971G>T p.K2657N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRM2 | c.738C>G p.N246K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.152); called by mutect2, varscan2
- CNIH3 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- CNN1 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CNOT6 | c.1558A>G p.S520G | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CNTNAP4 | c.1072-2A>T p.X358_splice | Splice Site (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- COL1A2 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.922); called by muse, mutect2
- COL4A4 | c.3356G>A p.R1119K | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CREBZF | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAAM2 | c.2030G>T p.R677M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACT1 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DIP2C | c.2821G>T p.G941W | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIPK1C | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLK2 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- DNAH9 | c.1514del p.S505Tfs*15 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- DOP1A | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DST | c.10207G>T p.E3403* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.8149T>A p.F2717I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.145); called by muse, mutect2
- DZIP3 | c.3442dup p.C1148Lfs*6 | Frame Shift Ins (INS) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- EIF3L | c.1656+3G>A | Splice Region (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- EML5 | c.3344G>T p.S1115I | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC7 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- FAM133B | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM47A | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- FANCM | c.3805A>G p.I1269V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- FAP | c.2102C>A p.A701E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FBXO10 | c.814T>C p.Y272H | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- FBXO21 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- FCRL5 | c.518G>C p.C173S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG2 | c.4528C>A p.H1510N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by mutect2, varscan2
- FOXD4 | c.67del p.E23Kfs*25 | Frame Shift Del (DEL) | VAF 27/135 reads (20%) | called by mutect2, pindel, varscan2
- FOXL3 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- FRYL | c.3082G>A p.A1028T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by muse, mutect2
- FUBP1 | c.838-2A>T p.X280_splice | Splice Site (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- FZR1 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- GALNT17 | c.1583T>C p.V528A | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GAREM2 | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, varscan2
- GLI2 | c.2044G>T p.D682Y (on ENST00000361492 / NM_001374353.1; = p.D699Y on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GNRHR | c.947C>A p.P316Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HMGCLL1 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- HOXB2 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- HOXD9 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2
- IFNA7 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IGHA1 | c.991C>A p.R331S | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- IGKV3D-20 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- KCNA2 | c.1407T>A p.N469K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.017); called by mutect2, varscan2
- KCNA3 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNH6 | c.1489A>G p.M497V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- KIAA1109 | c.12670T>C p.F4224L | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2
- KIF17 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LCA5 | c.2024C>G p.A675G | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- LINC01517 | n.352G>T | Splice Region (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- LRIT2 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- LRRN1 | c.1709A>G p.Y570C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MANEAL | c.1199C>A p.S400Y (on ENST00000373045 / NM_001113482.1; = p.S178Y on NM_152496.2) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP7 | c.879_895del p.S293Rfs*20 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | called by mutect2, pindel
- MC3R | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, varscan2
- MCM5 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- MED23 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MEGF6 | c.3002A>T p.Q1001L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, varscan2
- MFGE8 | c.713A>C p.N238T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- MLNR | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MOCS1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOCS1 | c.758-1G>T p.X253_splice | Splice Site (SNP) | VAF 31/237 reads (13%) | called by muse, mutect2, varscan2
- MRPS35 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- MS4A7 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- MSC | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by mutect2, varscan2
- MUC16 | c.17210C>A p.P5737Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- MUC19 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MUC5B | c.6823C>A p.H2275N | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYO15A | c.7155G>C p.K2385N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- MYO16 | c.4315C>A p.L1439M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MYO5C | c.4718G>T p.R1573M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NDC1 | c.1222+1G>T p.X408_splice | Splice Site (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- NKD2 | c.436A>T p.S146C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- NLRP3 | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- NLRP4 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NOD1 | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP58 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2
- OLIG2 | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- OLIG2 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR10K1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- OR2L2 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C6 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR5D14 | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- OR7A10 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- OXTR | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- PAMR1 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCBP3 | c.811T>A p.L271I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH15 | c.560T>A p.I187K | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA2 | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGA5 | c.1948G>T p.G650C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA8 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PCDHGC5 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCLO | c.11659C>A p.Q3887K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PCNX2 | c.5669G>T p.G1890V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDE4A | c.1558G>A p.D520N (on ENST00000380702 / NM_001111307.2; = p.D281N on NM_006202.3) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PEX5L | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PIK3CA | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2
- PKD1L2 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PKD1L3 | c.3148G>C p.G1050R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.7109C>A p.T2370K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PMM1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPM1A | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRCC | c.39G>T p.E13D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- PRDM10 | c.1427C>G p.P476R | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PROKR1 | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- PRPF3 | c.2030C>G p.S677C | Missense Mutation (SNP) | VAF 72/420 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, varscan2
- PRRC2C | c.2808dup p.P937Tfs*7 (on ENST00000367742; = p.P935Tfs*7 on NM_015172.4) | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, pindel
- RAB34 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RABGEF1 | c.123C>A p.N41K (on ENST00000439720 / NM_001287061.2; = p.N28K on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBMXL2 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RGSL1 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, varscan2
- RIOX2 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2
- RYR2 | c.3619C>A p.L1207I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, varscan2
- RYR3 | c.12200T>A p.F4067Y (on ENST00000389232; = p.F4068Y on NM_001036.6) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- S100A13 | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCFD1 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SCN10A | c.470A>C p.E157A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SCN5A | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- SCN7A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SCRN2 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- SEC24B | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2
- SEMA3C | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2357G>A p.G786E (on ENST00000354181 / NM_001365088.1; = p.G735E on NM_005135.2) | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC4A4 | c.2656C>A p.L886M (on ENST00000264485 / NM_001098484.3; = p.L842M on NM_003759.4) | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC7A1 | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC1A | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX14 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SP7 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPEF2 | c.2508-1G>C p.X836_splice | Splice Site (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- SRCAP | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSTR3 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ST3GAL3 | c.526A>T p.I176F (on ENST00000361392 / NM_174964.4; = p.I161F on NM_006279.5) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STK32B | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SV2C | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SYCE1 | c.99T>G p.I33M | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); called by muse, mutect2
- SYCP2 | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- TARBP2 | c.294dup p.S99Efs*22 (on ENST00000266987 / NM_134323.2; = p.S78Efs*22 on NM_004178.4) | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by pindel, varscan2
- TENM1 | c.3313T>A p.Y1105N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TEX13C | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TGIF2LX | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by mutect2, varscan2
- TMC5 | c.1831C>G p.Q611E (on ENST00000396229 / NM_001105248.1; = p.Q365E on NM_024780.5) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- TMEM168 | c.546G>T p.L182F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.764); called by mutect2, varscan2
- TRBV5-1 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by mutect2, varscan2
- TRHDE | c.1162T>C p.Y388H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRPM3 | c.3625G>A p.E1209K (on ENST00000357533 / NM_001366142.2; = p.E1064K on NM_020952.6) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- UBASH3B | c.465A>T p.K155N | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.184); called by muse, mutect2
- UTP4 | c.409T>G p.F137V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, varscan2
- UTRN | c.7236T>G p.N2412K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- VARS1 | c.1286A>T p.H429L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- VWA5B1 | c.1717A>G p.I573V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.194); called by muse, mutect2
- WDFY4 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- WDFY4 | c.5545G>T p.E1849* | Nonsense Mutation (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XCL2 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZC3H18 | c.1966G>T p.V656F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZDBF2 | c.6256A>T p.S2086C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- ZMAT3 | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF239 | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF260 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF551 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF804B | c.3277G>T p.E1093* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- ZNF804B | c.3958G>A p.G1320S | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZNF835 | c.1068C>G p.H356Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM4 | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AASDH | c.2070G>A p.L690= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- ADGB | c.1368T>A p.P456= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV58861702; called by muse, mutect2, varscan2
- ADGRG4 | c.7857T>C p.L2619= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- ANGPTL8 | c.207C>G p.L69= | Silent (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- ANKS1B | c.2394T>C p.L798= | Silent (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- ANO4 | c.1413G>A p.Q471= (on ENST00000392977 / NM_001286615.2; = p.Q436= on NM_178826.4) | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- AOX1 | c.1299A>T p.R433= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1157279678; called by muse, mutect2, varscan2
- ARHGEF5 | c.882T>C p.T294= | Silent (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- BIRC3 | c.1044A>G p.T348= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs200328626; called by muse, mutect2, varscan2
- C10orf71 | c.3684C>G p.P1228= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- C6orf15 | c.303G>T p.S101= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- CACNA2D2 | c.222C>G p.A74= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CADPS | c.3912G>A p.G1304= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- CFAP77 | c.160C>A p.R54= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1038529102; called by muse, mutect2, varscan2
- CLCA4 | c.2661T>G p.P887= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- CNBD1 | c.1257C>A p.T419= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs1425622050; called by muse, mutect2, varscan2
- CSF2RB | c.2181T>A p.S727= | Silent (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- ELOVL7 | c.228A>T p.V76= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- FAM126A | c.1419G>T p.G473= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs760232343; called by muse, mutect2, varscan2
- FANCM | c.1524T>C p.F508= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- FAT3 | c.5154A>G p.P1718= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- FBXW8 | c.609C>T p.L203= (on ENST00000309909; = p.L241= on NM_012174.1) | Silent (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2
- FGD2 | c.957C>A p.T319= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV51463945; called by muse, mutect2, varscan2
- FLT4 | c.3114G>T p.L1038= | Silent (SNP) | VAF 5/34 reads (15%) | called by mutect2, varscan2
- FSIP2 | c.2451T>C p.C817= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- FXYD6 | c.150G>T p.S50= | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2, varscan2
- GALNS | c.1398C>T p.S466= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- GPR158 | c.1285C>T p.L429= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- GPR88 | c.430C>A p.R144= | Silent (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- GRIN2B | c.1716G>T p.V572= | Silent (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- H2AC4 | c.15C>T p.G5= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs1023642472; called by muse, mutect2, varscan2
- H2BC13 | c.138G>A p.L46= | Silent (SNP) | VAF 35/213 reads (16%) | catalogued as COSV100704325, COSV62440339; called by muse, mutect2, varscan2
- HIVEP3 | c.6513G>T p.R2171= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- HRNR | c.687T>C p.S229= | Silent (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.258C>A p.G86= | Silent (SNP) | VAF 24/322 reads (7%) | called by muse, mutect2
- IGKV2-24 | c.276A>C p.A92= | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- KCNS2 | c.717A>G p.T239= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1391617453; called by muse, mutect2, varscan2
- KCNT1 | c.2718C>A p.S906= (on ENST00000488444; = p.S925= on NM_020822.3) | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- KRT81 | c.921G>T p.T307= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV100576897; called by muse, mutect2, varscan2
- KSR1 | c.1854G>T p.L618= (on ENST00000644974 / NM_001367810.1; = p.L503= on NM_014238.2) | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- LAMA4 | c.2607G>A p.V869= (on ENST00000230538 / NM_001105206.3; = p.V862= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/116 reads (19%) | called by muse, varscan2
- LEPR | c.2919C>A p.T973= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- MASP2 | c.1494A>G p.R498= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- MRC1 | c.4209T>A p.A1403= | Silent (SNP) | VAF 87/315 reads (28%) | called by muse, mutect2, varscan2
- MROH2B | c.3177C>G p.V1059= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- MUC16 | c.9894T>A p.S3298= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV67488156; called by muse, mutect2, varscan2
- MX2 | c.1185G>A p.E395= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- NAXE | c.699C>T p.I233= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- NLRP1 | c.4032G>C p.L1344= (on ENST00000572272 / NM_033004.4; = p.L1300= on NM_014922.5) | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- NTN5 | c.1425C>T p.C475= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1349564079; called by muse, mutect2
- NTNG2 | c.72C>A p.S24= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- OPRL1 | c.918C>T p.A306= | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- OR5T1 | c.621C>A p.I207= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- OTOP3 | c.1686C>T p.F562= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1635G>A p.E545= | Silent (SNP) | VAF 20/284 reads (7%) | catalogued as COSV50770073; called by muse, mutect2
- PIEZO1 | c.5511C>T p.T1837= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1383432397; called by muse, mutect2, varscan2
- PKHD1 | c.963C>A p.T321= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2, varscan2
- POTEH | c.1482C>T p.S494= | Silent (SNP) | VAF 21/536 reads (4%) | catalogued as COSV100624595; called by muse, mutect2
- PRAMEF12 | c.1359T>C p.T453= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs1055293909; called by muse, mutect2, varscan2
- RAB34 | c.105C>T p.R35= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs988539920; called by muse, mutect2, varscan2
- RGS2 | c.411T>C p.T137= | Silent (SNP) | VAF 37/215 reads (17%) | called by muse, mutect2, varscan2
- RTEL1 | c.873G>A p.Q291= | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- SCN3A | c.2439C>A p.A813= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- SGCB | c.223C>T p.L75= | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- SLC12A6 | c.207G>C p.S69= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs757882297; called by muse, mutect2, varscan2
- SLC24A2 | c.609T>G p.V203= | Silent (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- SLC7A9 | c.784C>T p.L262= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs778178019; called by muse, mutect2, varscan2
- SNAP91 | c.2613C>A p.A871= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- SPATA17 | c.111T>A p.V37= | Silent (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- STRN | c.1944A>G p.Q648= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.3909T>A p.G1303= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- SYT16 | c.1212G>T p.T404= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as rs200293604, COSV70859602; called by muse, mutect2, varscan2
- TFAP2D | c.294G>A p.S98= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV50408104, COSV50443394; called by muse, mutect2, varscan2
- THEMIS2 | c.1398T>A p.T466= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- TIMM50 | c.981C>T p.A327= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs375884282; called by muse, mutect2, varscan2
- TMEM132C | c.1572C>A p.P524= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- TRIM10 | c.210G>T p.R70= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100938761; called by mutect2, varscan2
- TRIM69 | c.1383C>G p.T461= (on ENST00000329464 / NM_182985.5; = p.T302= on NM_080745.5) | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2, varscan2
- TRPM8 | c.2640C>A p.A880= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- TRUB1 | c.432A>G p.S144= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- TSGA13 | c.327C>A p.T109= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.82890C>A p.G27630= (on ENST00000591111; = p.G20206= on NM_003319.4) | Silent (SNP) | VAF 41/257 reads (16%) | called by muse, mutect2, varscan2
- VPS13B | c.4891C>T p.L1631= | Silent (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- ZNF431 | c.747A>G p.R249= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs748897785; called by muse, mutect2, varscan2
- ZNF831 | c.3783G>T p.V1261= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- ABR | c.1962-332A>G | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2111A>T | RNA (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- AC104794.1 | chr2:10086073 A>T | 3'Flank (SNP) | VAF 10/89 reads (11%) | called by muse, varscan2
- ADAM6 | n.1460G>T | RNA (SNP) | VAF 8/100 reads (8%) | catalogued as rs532526524; called by muse, mutect2
- ADGRE5 | c.*4C>A | 3'UTR (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100105701 T>G | 5'Flank (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- AGAP7P | n.1733del | RNA (DEL) | VAF 42/136 reads (31%) | called by mutect2, varscan2
- AICDA | c.*17T>G | 3'UTR (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- AL449403.2 | n.272G>T | RNA (SNP) | VAF 27/221 reads (12%) | called by muse, mutect2, varscan2
- AP3S1 | chr5:115841585 G>A | 5'Flank (SNP) | VAF 8/43 reads (19%) | catalogued as rs1465600242; called by muse, mutect2, varscan2
- ASAH2 | c.510+2656T>C | Intron (SNP) | VAF 20/222 reads (9%) | catalogued as rs1430275416; called by muse, mutect2
- ATP1A2 | c.*44G>C | 3'UTR (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- CASC15 | chr6:22147155 G>A | 5'Flank (SNP) | VAF 28/140 reads (20%) | catalogued as rs879606052; called by mutect2, varscan2
- CATSPER2 | c.562-45G>A | Intron (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- CEP41 | c.*4330G>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- CMTM5 | c.-21G>T | 5'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CSDE1 | c.1-1674C>A | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as COSV54753033; called by muse, mutect2, varscan2
- CSF2RA | c.810+48G>T | Intron (SNP) | VAF 34/112 reads (30%) | catalogued as COSV62623332; called by muse, varscan2
- DAAM2 | c.258+64T>A | Intron (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- DCAF17 | c.-164C>T | 5'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- DCLK2 | c.2074-2490A>T | Intron (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- DMD | c.31+83148T>A | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+441A>G | Intron (SNP) | VAF 12/42 reads (29%) | catalogued as rs1170830927; called by muse, mutect2, varscan2
- FAM78B | c.*453G>T | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1093C>A | RNA (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- FOLH1B | n.1405G>T | RNA (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- GDF3 | c.-42G>T | 5'UTR (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- GUSBP10 | n.577G>T | RNA (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- GVINP1 | n.2752G>C | RNA (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- HBG1 | c.315+33T>C | Intron (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2231+22390G>T | Intron (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- HOXC4 | c.-124+16564del | Intron (DEL) | VAF 6/8 reads (75%) | catalogued as rs1565746105; called by mutect2, varscan2
- IL23R | c.798+620A>T | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- KLRA1P | n.109G>T | RNA (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- MGAM | c.4618+11275G>T | Intron (SNP) | VAF 11/169 reads (7%) | called by muse, mutect2
- MUCL3 | c.947-555G>T | Intron (SNP) | VAF 31/177 reads (18%) | called by muse, mutect2, varscan2
- MYCT1 | c.*507C>A | 3'UTR (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- MYO15A | c.3693-41A>T | Intron (SNP) | VAF 10/60 reads (17%) | called by mutect2, varscan2
- NPHS2 | c.873+25G>T | Intron (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- PRKCA | c.1713+126G>T | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- PRPF3 | c.*40C>G | 3'UTR (SNP) | VAF 64/262 reads (24%) | called by muse, varscan2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 8/102 reads (8%) | catalogued as rs1426585233; called by muse, mutect2
- RBM44 | c.-98-1943C>A | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- ROBO1 | c.*32G>C | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- RPS26P15 | n.255G>T | RNA (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- SCN4B | c.*3344C>G | 3'UTR (SNP) | VAF 16/142 reads (11%) | called by muse, varscan2
- SERPINA6 | c.613+12C>A | Intron (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- SLC6A2 | chr16:55705165 G>T | 3'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-47950C>T | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as rs1555168645, COSV101044206; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-45766A>G | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1013088884; called by muse, mutect2
- SNORD115-21 | n.66G>C | RNA (SNP) | VAF 11/244 reads (5%) | called by muse, mutect2
- SNORD115-37 | n.14G>T | RNA (SNP) | VAF 8/67 reads (12%) | called by mutect2, varscan2
- SPATA31C1 | n.1033C>G | RNA (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- SPATA31D5P | n.230C>A | RNA (SNP) | VAF 10/80 reads (13%) | catalogued as rs1251377360; called by muse, mutect2, varscan2
- STXBP4 | c.945+304G>A | Intron (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- TFDP2 | c.-39T>G | 5'UTR (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TNS1 | c.-50C>A | 5'UTR (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- TPD52 | c.-10G>T | 5'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- UBA1 | c.1-458C>G | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2
- WTAP | c.87-48A>G | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs552505523; called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 10/106 reads (9%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
- ZNF451 | c.-34G>T | 5'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- ZNF521 | c.41-75G>A | Intron (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- ZNF778 | c.*5437G>T | 3'UTR (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
